Gene-level copy-number profile of tumor specimen ALCH-B2O1-TTP1-B from ALCHEMIST case ALCH-B2O1, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 42.3 years (15,454 days).
Specimen ALCH-B2O1-TTP1-B: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 02637f57-d022-43c6-9eba-8e0052c4eb0d.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2O1-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,223 have no estimate.
https://portal.gdc.cancer.gov/files/868ab3cc-7202-422c-8846-fb7746a67b50

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 11; copy number 1: 7,219; copy number 2: 43,267; copy number 3: 7,893; copy number 4: 6; copy number 5: 2; copy number 7: 2.

Homozygous deletions (total copy number 0; autosomes only): 11 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:133,181,409–133,238,549, 5 genes (within-gene range 0–2): ZNF268, AC226150.1, ANHX, RNU6-717P, Y_RNA.
- chr16:32,388,135–32,436,203, 1 gene: AC138915.2.
- chr16:32,454,612–32,636,045, 5 genes: AC138915.3, AC138915.1, ABCD1P3, AC137800.1, AC133569.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:18,333,726–18,341,859, 1 gene, copy number 7: CR383658.1.
- chr14:18,395,626–18,568,790, 3 genes, copy number 5–7: CR383658.2, BNIP3P6, CR383656.13.

Autosomal genes at a single copy (total copy number 1): 5,921. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
